Somatic mutation profile of tumor specimen TCGA-DX-AB3B-01A (aliquot TCGA-DX-AB3B-01A-11D-A417-09) from TCGA case TCGA-DX-AB3B, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 28.3 years (10,337 days).
Specimen TCGA-DX-AB3B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c1381f1-1160-44b6-b7ad-9dfde901ae69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB3B-10A (Blood Derived Normal), aliquot TCGA-DX-AB3B-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c49229d-f05d-4029-8650-175230d6801e

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 19, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABTB2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54392851; called by muse, mutect2, varscan2
- ADGRA2 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs143113584; called by muse, mutect2, varscan2
- APBA1 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV99595477; called by muse, mutect2, varscan2
- COL4A2 | c.1691T>C p.V564A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.024); catalogued as COSV100847234; called by muse, mutect2, varscan2
- DMD | c.6088G>T p.D2030Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100818188; called by muse, mutect2, varscan2
- H3C3 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV100778246, COSV63550763; called by muse, mutect2, varscan2
- KHNYN | c.272T>A p.I91N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99249411; called by muse, mutect2, varscan2
- KMT2C | c.14657A>C p.Y4886S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100067243; called by muse, mutect2, varscan2
- LAMA1 | c.3022G>T p.D1008Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101055081; called by mutect2, varscan2
- PCDHB8 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 60/1152 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1398272747, COSV50833754; called by muse, mutect2
- PLXND1 | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100139059; called by muse, mutect2, varscan2
- SCN2A | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51843815; called by muse, mutect2, varscan2
- SCN8A | c.3107A>C p.E1036A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.393); catalogued as COSV100633277, COSV61984182; called by muse, varscan2
- SP140 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV100613393; called by muse, mutect2, varscan2
- SYNPO2L | c.2136G>T p.K712N (on ENST00000394810 / NM_001114133.3; = p.K488N on NM_024875.5) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV65738836; called by muse, mutect2
- TMEM236 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1564590552; called by muse, mutect2, varscan2
- TSPYL6 | c.1202T>C p.I401T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as COSV100336301; called by muse, mutect2, varscan2
- TULP2 | c.109C>G p.R37G | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99617727; called by muse, mutect2, varscan2
- NCOA4 | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PMS1 | c.133_135del p.X45_splice | Splice Site (DEL) | VAF 13/111 reads (12%) | called by mutect2, pindel, varscan2
- SLC17A4 | c.1201C>T p.L401= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100930494; called by muse, mutect2, varscan2
- TRAPPC9 | c.387C>T p.R129= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV101226709; called by muse, mutect2, varscan2
- WNT2 | c.123C>T p.C41= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs140391205, COSV55412856; called by muse, mutect2, varscan2
